Somatic mutation profile of tumor specimen TCGA-GR-7351-01A (aliquot TCGA-GR-7351-01A-11D-2210-10) from TCGA case TCGA-GR-7351, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 57.0 years (20,812 days).
Specimen TCGA-GR-7351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ba9e53e-e8ff-4894-8f66-e7c57ac68827.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GR-7351-10A (Blood Derived Normal), aliquot TCGA-GR-7351-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c46b4f54-14ac-41e5-9520-78512649515d

The open-access MAF lists 330 somatic variants for this specimen: 258 protein-altering or splice-affecting, 64 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 230, Silent 64, Nonsense Mutation 10, Splice Site 8, RNA 4, Frame Shift Del 3, Frame Shift Ins 3, Splice Region 2, 5'UTR 2, Translation Start Site 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.644A>T p.K215M | Missense Mutation (SNP) | VAF 84/186 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62717709, COSV62720893; called by muse, mutect2, varscan2
- FOXO1 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 40/188 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65429155, COSV65429409; called by muse, mutect2, varscan2
- KCNJ2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473653, CM053932; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV55393673; called by muse, mutect2, varscan2
- ADAMTS12 | c.2479T>A p.F827I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV61265253; called by muse, mutect2, varscan2
- ADAMTS18 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 28/119 reads (24%) | catalogued as rs775431905, COSV51417329; called by muse, mutect2, varscan2
- ARHGAP12 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as rs34750454; called by muse, mutect2, varscan2
- ASXL3 | c.6742C>T p.R2248* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs1268450717, COSV52459252; called by muse, mutect2, varscan2
- BIRC6 | c.13069C>T p.P4357S | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70204576; called by muse, mutect2, varscan2
- BTG2 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV104392371; called by muse, varscan2
- BTG2 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as COSV51856494, COSV99305486; called by muse, varscan2
- C6orf118 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs1278555030, COSV100024622; called by muse, mutect2, varscan2
- CARD11 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62717294; called by muse, mutect2, varscan2
- CARF | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs766308672; called by muse, mutect2, varscan2
- CCND3 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1006519914; called by muse, mutect2, varscan2
- CD83 | c.153+1G>A p.X51_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as rs1312964957; called by muse, mutect2, varscan2
- CDH8 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV54885979; called by muse, mutect2, varscan2
- CHD1 | c.2956G>T p.E986* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as rs918509859; called by muse, mutect2, varscan2
- CIITA | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60860692; called by muse, mutect2, varscan2
- CLCNKA | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); catalogued as rs533923354; called by muse, mutect2, varscan2
- COL1A1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1175987778; called by muse, mutect2, varscan2
- CYP1B1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs750132418, COSV99572671; called by muse, mutect2, varscan2
- EBI3 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147339690; called by muse, varscan2
- EP400 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1273668450; called by muse, mutect2
- FAF2 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs772364209; called by muse, mutect2, varscan2
- FAM102A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs764999375; called by muse, varscan2
- FCRL3 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs201961888, COSV63840559; called by muse, varscan2
- FOXA2 | c.178G>A p.A60T (on ENST00000377115 / NM_153675.3; = p.A66T on NM_021784.5) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs769823311, COSV65795828; called by muse, mutect2, varscan2
- GATA2 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV62003985; called by muse, mutect2, varscan2
- GCH1 | c.329A>G p.Q110R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as CD093880; called by muse, varscan2
- GRIK4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs753839952, COSV101483608; called by muse, mutect2, varscan2
- H2AC15 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 46/113 reads (41%) | catalogued as rs1216977325; called by muse, mutect2, varscan2
- H2AC8 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.22); catalogued as rs756106574; called by muse, mutect2, varscan2
- HHEX | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 3/7 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs994627049; called by muse, mutect2
- HLTF | c.2639G>A p.R880H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766833541; called by muse, mutect2, varscan2
- HYAL2 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.722); catalogued as rs143678537; called by muse, mutect2, varscan2
- IGHG1 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as rs1482098096; called by muse, mutect2, varscan2
- IGKV1D-8 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs369629795; called by muse, varscan2
- IGKV1D-8 | c.292A>T p.S98C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1351571546; called by muse, varscan2
- IGLV3-16 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs752247264; called by muse, varscan2
- IGLV4-60 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs772208150, COSV66503857; called by muse, varscan2
- IGLV8-61 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs566370819, COSV66502554; called by muse, mutect2, varscan2
- ITIH6 | c.2728A>G p.S910G | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV54489273, COSV54495560; called by muse, mutect2
- JAK1 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs1403227052, COSV61093248; called by muse, mutect2, varscan2
- KCNU1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs180964986, COSV67755904; called by muse, mutect2, varscan2
- KHDRBS1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56983559; called by muse, mutect2, varscan2
- LEMD3 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs779865961; called by muse, mutect2, varscan2
- LMX1A | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767091330; called by muse, mutect2, varscan2
- LTB | c.200A>G p.Q67R | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs532757438; called by muse, varscan2
- MAGI2 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV62642519; called by muse, mutect2, varscan2
- MRC2 | c.3296C>T p.T1099M | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs201851897, COSV57639722; called by muse, mutect2, varscan2
- MROH1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.601); catalogued as rs374952645; called by muse, mutect2, varscan2
- MYO9A | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs772538066, COSV61849412; called by muse, mutect2, varscan2
- NCAPD2 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs776884151, COSV59698679; called by muse, mutect2, varscan2
- NECTIN1 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs200377205, COSV50611809; called by muse, mutect2, varscan2
- NEK5 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs1029726697, COSV62880100; called by muse, mutect2, varscan2
- NELL1 | c.652A>T p.T218S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV54319640; called by muse, mutect2, varscan2
- NLRP5 | c.2743A>G p.S915G | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs746392011; called by muse, mutect2, varscan2
- NMUR2 | c.799A>C p.N267H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV54919360; called by muse, mutect2
- OR10J1 | c.677A>C p.K226T | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV71128092; called by muse, mutect2, varscan2
- OR2T27 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1226757382; called by muse, mutect2, varscan2
- PAX5 | c.38G>C p.S13T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV63914775; called by muse, mutect2, varscan2
- PAX5 | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1338245101; called by muse, mutect2, varscan2
- PCDHA13 | c.1357C>G p.P453A | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1446947181; called by muse, mutect2
- PCDHB16 | c.2320T>G p.F774V | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs1554282487; called by muse, mutect2, varscan2
- PCSK5 | c.1757-2A>C p.X586_splice | Splice Site (SNP) | VAF 10/152 reads (7%) | catalogued as COSV100949612; called by muse, mutect2
- PIM1 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV65164628, COSV65165383, COSV65165412; called by muse, mutect2, varscan2
- PON1 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99732103; called by muse, mutect2, varscan2
- PPARG | c.1446G>T p.Q482H (on ENST00000287820 / NM_015869.5; = p.Q452H on NM_005037.7) | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV55146054; called by muse, mutect2, varscan2
- PRDM9 | c.203C>A p.A68D | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV57006567, COSV99690518; called by muse, mutect2, varscan2
- PROC | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769900251, CM930605; called by muse, mutect2, varscan2
- PRRT3 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); catalogued as rs1428192304; called by muse, mutect2, varscan2
- PTPRD | c.3931C>T p.P1311S | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1214286773, COSV61962750; called by muse, mutect2, varscan2
- RGS1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV66505757; called by muse, varscan2
- ROR2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1347793502; called by muse, mutect2
- SCAF8 | c.475+2T>A p.X159_splice | Splice Site (SNP) | VAF 24/57 reads (42%) | catalogued as COSV65790037; called by muse, mutect2, varscan2
- SGK1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV52810644; called by muse, varscan2
- SGK1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as rs1223620188, COSV52804972; called by muse, varscan2
- SGK1 | c.153C>T p.H51= | Splice Region (SNP) | VAF 20/64 reads (31%) | catalogued as COSV52804588; called by muse, varscan2
- SLC22A15 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs201564754, COSV65678379; called by muse, mutect2, varscan2
- SLC38A10 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057072050; called by muse, mutect2, varscan2
- SNAP25 | c.114+1G>A p.X38_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as rs1374369238; called by muse, mutect2, varscan2
- SPAG17 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148273524; called by muse, mutect2, varscan2
- SPTLC3 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs200308499; called by muse, mutect2, varscan2
- SSX3 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs782421029, COSV100035387; called by muse, varscan2
- STAT3 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV52884348, COSV52884550, COSV99232344; called by muse, mutect2, varscan2
- SYNGAP1 | c.1970G>A p.W657* | Nonsense Mutation (SNP) | VAF 10/115 reads (9%) | catalogued as rs1554121820; called by muse, mutect2
- TLR3 | c.1238A>C p.N413T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs1388869607, COSV57168084; called by muse, mutect2
- TMEM135 | c.892T>G p.F298V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1334766279; called by muse, mutect2, varscan2
- TRAK1 | c.1807C>T p.P603S (on ENST00000327628 / NM_001349247.2; = p.P545S on NM_014965.5) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs375255978; called by muse, mutect2, varscan2
- TREX2 | c.496G>T p.D166Y (on ENST00000334497; = p.D123Y on NM_080701.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781885067, COSV57850119; called by muse, mutect2, varscan2
- UTP20 | c.5755G>A p.G1919R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs779982797; called by muse, mutect2, varscan2
- WDR24 | c.241C>T p.R81C (on ENST00000248142; = p.R19C on NM_032259.4) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs754016147; called by muse, mutect2, varscan2
- WNT7B | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs147287645; called by muse, mutect2, varscan2
- ZEB2 | c.73+1G>A p.X25_splice | Splice Site (SNP) | VAF 22/43 reads (51%) | catalogued as CD097149, CS031468, COSV57956650; called by muse, mutect2, varscan2
- ZFAND2B | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs745579852; called by muse, mutect2, varscan2
- ZFP2 | c.761G>C p.S254T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs781178247; called by muse, mutect2, varscan2
- ZFP90 | c.1333A>G p.T445A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs779399319, COSV68050680; called by muse, mutect2, varscan2
- ZPLD1 | c.202C>A p.L68M (on ENST00000466937 / NM_001329788.1; = p.L84M on NM_175056.2) | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.541); catalogued as COSV60355739; called by muse, mutect2, varscan2
- ABCB4 | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2
- ABHD5 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGGF1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AKAP3 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ALDH9A1 | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP18 | c.1129T>G p.C377G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- ATG2A | c.5537A>C p.D1846A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRNL1 | c.2699C>T p.T900I | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- B2M | c.337_340del p.V113Sfs*34 (on ENST00000559916; = p.V113Sfs*31 on NM_004048.4) | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel
- BEST2 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BRINP1 | c.2024A>C p.Q675P | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- BRINP3 | c.1479A>C p.Q493H | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- C5orf51 | c.355-2A>C p.X119_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- CCDC15 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CCDC54 | c.492A>C p.K164N | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- CCDC85A | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCR2 | c.563A>C p.Y188S | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CD177 | c.1053T>G p.C351W | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD27 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CD48 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPG | c.1488+2T>C p.X496_splice | Splice Site (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- CEP164 | c.2219T>C p.L740P | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP46 | c.5756T>C p.V1919A | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CFHR2 | c.198T>A p.F66L | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.013); called by muse, mutect2
- CHD5 | c.2137T>G p.F713V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CHRDL1 | c.826A>C p.I276L (on ENST00000372045; = p.I282L on NM_145234.4) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CIITA | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- CLCA2 | c.1907T>A p.L636H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CLN8 | c.230G>C p.S77T | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); called by muse, mutect2
- COL24A1 | c.2153A>C p.E718A | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CSMD1 | c.2444T>A p.V815D (on ENST00000520002; = p.V814D on NM_033225.6) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1A1 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CTSE | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXCL14 | c.50C>T p.A17V (on ENST00000337225; = p.A5V on NM_004887.5) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP11B2 | c.920A>C p.N307T | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DACT1 | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- DAO | c.844T>G p.F282V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DCDC2 | c.451A>C p.N151H | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- DDN | c.1264dup p.A422Gfs*35 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- DDX23 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DDX4 | c.2125T>G p.F709V | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.8545A>C p.S2849R | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJA2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DST | c.17619A>C p.Q5873H (on ENST00000361203 / NM_001374722.1; = p.Q3570H on NM_015548.5) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DUSP8 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- DYNC1I1 | c.340T>A p.S114T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- EDIL3 | c.1021T>C p.F341L | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- EDRF1 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFNB1 | c.996A>C p.Q332H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EGR1 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, varscan2
- EP300 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBXL22 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGBP | c.5044C>T p.H1682Y | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- FEM1A | c.1262A>C p.Q421P | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FFAR4 | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FLAD1 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GALNT7 | c.661T>C p.S221P | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GALNT8 | c.437A>C p.K146T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- GDF9 | c.226T>G p.S76A | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- H3C13 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.204); called by muse, mutect2
- H4C9 | c.215C>G p.T72S | Missense Mutation (SNP) | VAF 86/131 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- IGKV1D-8 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, varscan2
- IGKV1D-8 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- IGLV3-9 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- IGLV4-3 | c.143_168del p.S48Tfs*14 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- IGSF10 | c.2128A>C p.K710Q | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2
- ILDR1 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ISG20 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ITIH6 | c.3547A>C p.K1183Q | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IVL | c.375A>C p.E125D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- IZUMO1 | c.548A>C p.E183A | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- JAK1 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF1A | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- KIF2A | c.866T>G p.V289G | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KNDC1 | c.4490C>T p.A1497V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KRT7 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- KRTAP9-2 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- LAMA1 | c.8331T>G p.F2777L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LAMA4 | c.1470A>T p.E490D (on ENST00000230538 / NM_001105206.3; = p.E483D on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LDHAL6A | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LIMD2 | c.8A>T p.Q3L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRC4C | c.1257A>C p.Q419H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LYST | c.9250G>A p.D3084N | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MISP | c.1909T>C p.W637R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MMP24 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MPLKIP | c.323A>T p.Q108L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MTUS1 | c.2885T>G p.V962G (on ENST00000262102 / NM_001363061.1; = p.V128G on NM_020749.4) | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- MYH10 | c.3677A>C p.K1226T | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYO6 | c.1586T>G p.L529W | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAA15 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- NLRP8 | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NOP9 | c.810G>A p.V270= | Splice Region (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- NPHP4 | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NUDC | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- OR4A47 | c.761T>G p.F254C | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); called by muse, mutect2
- OR6A2 | c.189dup p.L64Sfs*3 | Frame Shift Ins (INS) | VAF 27/145 reads (19%) | called by mutect2, pindel, varscan2
- P2RY8 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PARK7 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PBX1 | c.459A>C p.K153N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDH17 | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCDHAC1 | c.447A>T p.Q149H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PCDHB11 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PCIF1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PEG3 | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PIGW | c.1111T>G p.L371V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PMEPA1 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- POLQ | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR2A | c.3365C>G p.P1122R | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPFIBP2 | c.1517A>C p.K506T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PRKAA1 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKDC | c.2057T>G p.V686G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PTPRD | c.4530A>C p.E1510D | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- PUS3 | c.970T>G p.L324V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- R3HDM1 | c.2432A>T p.Q811L | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RABGGTB | c.909A>C p.E303D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP17 | c.688T>G p.F230V | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RFC4 | c.875_876del p.V292Gfs*7 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by pindel, varscan2
- RP1 | c.2299A>G p.N767D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- S100A7A | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAMD9L | c.4221A>C p.K1407N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SEC61A1 | c.128T>C p.L43S | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, varscan2
- SETD4 | c.296A>C p.K99T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SETD5 | c.966C>G p.Y322* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- SF3B1 | c.1300A>G p.T434A | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SGK1 | c.430A>T p.M144L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SGK1 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.142); called by muse, varscan2
- SH3PXD2B | c.1974A>C p.E658D | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SIRPB2 | c.249A>C p.E83D | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SLC23A1 | c.935dup p.L313Pfs*22 | Frame Shift Ins (INS) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- SLCO1B1 | c.1367T>G p.L456R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SORCS1 | c.1889T>G p.L630R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORCS3 | c.2627A>C p.E876A | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SOX5 | c.1092C>A p.N364K | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.206); called by muse, mutect2
- SOX6 | c.1045A>G p.N349D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPIDR | c.1718T>A p.L573Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- STAB1 | c.7006T>G p.S2336A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by mutect2, varscan2
- SUV39H1 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SYNE3 | c.2797C>T p.L933F | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TANK | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- TBX15 | c.1602A>C p.K534N (on ENST00000369429 / NM_001330677.2; = p.K428N on NM_152380.3) | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- TENM1 | c.5188T>G p.F1730V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TENM3 | c.6403G>T p.D2135Y | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TET2 | c.3409+2dup p.X1137_splice (on ENST00000380013 / NM_001127208.3; = p.K1138* on NM_017628.4) | Splice Site (INS) | VAF 67/262 reads (26%) | called by mutect2, pindel, varscan2
- TET3 | c.3100C>T p.R1034* | Nonsense Mutation (SNP) | VAF 69/131 reads (53%) | called by muse, mutect2, varscan2
- TIGD2 | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2
- TMEM219 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- TNF | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- TOX3 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTC30A | c.1184A>C p.K395T | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- UNC13B | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VEPH1 | c.1823T>G p.L608R | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- VGLL2 | c.64T>G p.Y22D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VN1R2 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- WDR72 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB16 | c.1724A>G p.E575G | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF582 | c.1152A>C p.Q384H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ZNF597 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ZNF658 | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNRF3 | c.1648G>A p.D550N (on ENST00000544604 / NM_001206998.2; = p.D450N on NM_032173.3) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ADGRB3 | c.399A>C p.V133= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2
- AFAP1L1 | c.1260C>T p.P420= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV99695781; called by muse, mutect2
- AL031777.2 | c.279G>A p.E93= | Silent (SNP) | VAF 29/152 reads (19%) | catalogued as COSV61911739, COSV61912554; called by muse, mutect2, varscan2
- ALB | c.1081A>C p.R361= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs1222187655; called by muse, mutect2, varscan2
- AMER1 | c.180T>C p.F60= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as rs1354990829; called by muse, mutect2, varscan2
- ARHGAP32 | c.3756C>T p.P1252= (on ENST00000310343 / NM_001378025.1; = p.P903= on NM_014715.4) | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as rs376118787; called by muse, mutect2, varscan2
- ARID4A | c.2451A>C p.A817= | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- BTG2 | c.102G>A p.R34= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs1466877644, COSV51856911, COSV99305605, COSV99305919; called by muse, varscan2
- CIT | c.1335C>T p.S445= | Silent (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- COL12A1 | c.7452C>T p.D2484= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs778626937, COSV59389573, COSV59401302; called by muse, mutect2, varscan2
- COL24A1 | c.1005A>G p.K335= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- COL6A6 | c.4356A>T p.G1452= | Silent (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- CWF19L2 | c.654G>A p.S218= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs201136952, COSV56520592; called by muse, mutect2, varscan2
- DUSP8 | c.483G>T p.L161= | Silent (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- FABP4 | c.381A>G p.R127= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs1237685386; called by muse, mutect2, varscan2
- FAM135B | c.3285T>C p.F1095= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- FAM71D | c.1068T>C p.S356= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- FHIT | c.39T>G p.S13= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- GATM | c.522T>C p.V174= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs1007730795; called by muse, mutect2, varscan2
- GNB2 | c.48C>T p.N16= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- GRHL2 | c.468G>A p.T156= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs768605732, COSV52549519; called by muse, mutect2, varscan2
- H2AC6 | c.150G>A p.V50= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs139293879; called by muse, mutect2, varscan2
- H2BC13 | c.318G>A p.E106= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs563781327; called by muse, mutect2, varscan2
- HCN1 | c.1170C>T p.V390= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as rs369683016; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSP90AA1 | c.423T>C p.A141= | Silent (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- IGHG2 | c.240C>T p.T80= | Silent (SNP) | VAF 64/163 reads (39%) | called by muse, mutect2, varscan2
- IGHV3-30 | c.292C>T p.L98= | Silent (SNP) | VAF 11/178 reads (6%) | catalogued as rs779213628; called by muse, mutect2
- IGLV2-23 | c.177G>A p.Q59= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs11558640; called by muse, mutect2, varscan2
- JAKMIP1 | c.1635G>A p.E545= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV99291054; called by muse, mutect2, varscan2
- KCNH7 | c.3423T>G p.T1141= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV59783228; called by muse, mutect2, varscan2
- KCNQ3 | c.1761A>G p.K587= | Silent (SNP) | VAF 60/152 reads (39%) | called by muse, mutect2, varscan2
- KLHL42 | c.1194G>A p.G398= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV67145581; called by muse, mutect2, varscan2
- KRTAP27-1 | c.264T>G p.T88= | Silent (SNP) | VAF 42/214 reads (20%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.420T>C p.Y140= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs1238978606; called by muse, mutect2, varscan2
- MBOAT7 | c.444C>T p.S148= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as rs1354787690, COSV55477634; called by muse, mutect2, varscan2
- MN1 | c.3723C>T p.D1241= | Silent (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- MRPS12 | c.45T>G p.T15= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs780167000; called by muse, mutect2, varscan2
- MRPS5 | c.339A>G p.G113= | Silent (SNP) | VAF 80/255 reads (31%) | called by muse, mutect2, varscan2
- MXRA5 | c.5733T>A p.G1911= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- MYO7B | c.3052C>T p.L1018= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- NCKAP1 | c.1332A>G p.E444= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- NRIP1 | c.1836A>G p.K612= | Silent (SNP) | VAF 46/202 reads (23%) | called by muse, mutect2, varscan2
- OFD1 | c.2967C>T p.D989= | Silent (SNP) | VAF 42/189 reads (22%) | called by muse, mutect2, varscan2
- OR2J3 | c.600G>A p.L200= | Silent (SNP) | VAF 17/294 reads (6%) | catalogued as rs1362389400, COSV101013553; called by muse, mutect2
- OR6C76 | c.648T>G p.T216= | Silent (SNP) | VAF 48/147 reads (33%) | called by muse, mutect2, varscan2
- PARP11 | c.360C>T p.N120= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs1419568704; called by muse, mutect2, varscan2
- PCDHA1 | c.1158T>G p.T386= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.687C>T p.R229= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV99532727; called by muse, mutect2, varscan2
- PRAMEF4 | c.240C>T p.F80= | Silent (SNP) | VAF 65/192 reads (34%) | called by muse, mutect2, varscan2
- PRKD1 | c.2334C>T p.S778= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs749756622; called by muse, mutect2, varscan2
- RANBP6 | c.3261A>T p.V1087= | Silent (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- RIPK4 | c.1821A>C p.R607= (on ENST00000352483; = p.R559= on NM_020639.3) | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- RSAD1 | c.1176G>A p.E392= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- RTL9 | c.2913T>G p.A971= | Silent (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- RTN3 | c.1059T>C p.D353= (on ENST00000377819 / NM_001265589.2; = p.D334= on NM_201428.3) | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- SCN9A | c.3816T>G p.T1272= (on ENST00000303354; = p.T1261= on NM_002977.3) | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- SGK1 | c.201G>A p.E67= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, varscan2
- SLC26A7 | c.595T>C p.L199= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs751864755; called by muse, mutect2, varscan2
- SLC2A9 | c.339T>C p.T113= | Silent (SNP) | VAF 56/186 reads (30%) | catalogued as rs748541141; called by muse, mutect2, varscan2
- SMS | c.354A>G p.G118= | Silent (SNP) | VAF 26/236 reads (11%) | called by muse, mutect2, varscan2
- SNTB1 | c.1401T>C p.T467= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs867786478; called by muse, mutect2, varscan2
- SNX5 | c.19T>C p.L7= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- YBX1 | c.177T>C p.V59= | Silent (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- ZNF577 | c.1336A>C p.R446= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, varscan2
- C12orf77 | n.529C>A | RNA (SNP) | VAF 54/190 reads (28%) | called by muse, varscan2
- C12orf77 | n.426G>A | RNA (SNP) | VAF 38/156 reads (24%) | called by muse, varscan2
- CLN3 | c.-1G>C | 5'UTR (SNP) | VAF 15/37 reads (41%) | catalogued as rs201274333; called by muse, mutect2, varscan2
- DNAH8 | chr6:38723084 C>T | 5'Flank (SNP) | VAF 26/95 reads (27%) | catalogued as rs757958716; called by muse, mutect2, varscan2
- MIR1269A | n.22G>T | RNA (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- MIR655 | n.28T>G | RNA (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-18A>C | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- SGK1 | c.-1G>A | 5'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, varscan2
